Surgical pathology report (de-identified scan), TCGA case TCGA-NC-A5HT, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - CHUV, specimen TCGA-NC-A5HT-01A (Primary Tumor).

ICD-0-3

Carcinoma, Squamous cell NOS
8070/3
Site: (R) Lung, upper & lower lobes
C34.8
JW 2/1/13

Synoptic translated report

Site : Right lung superior and middle lobes

☒ Central ☐ Peripheral ☐ NA

Number of lesion :

1. Lung squamous cell carcinoma

Tumor size:

1. 4.7 cm (diameter)

Visceral pleural invasion: ☐ Yes ☒ No ☐ NA

Chest wall invasion : ☐ Yes ☒ No ☐ NA

Histological diagnosis : Moderately differentiated squamous cell carcinoma

Node status : N1 (7/19)

TNM : pT3 N1 (7/19) R0

Pathologist signature:

Date:

Criteria	JW 1/30/13	Yes	No
Disputed Discrepancy			✓
R 7A Discrepancy			✓
Site: Malignancy History			✓
Case is (in file)			

Source: NCI Genomic Data Commons file c9769220-2a41-4a1f-bc62-ee4bdb28c219 (TCGA-NC-A5HT.81068415-BBAA-432E-97C2-14E6B559D41A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).